Gene-level copy-number profile of tumor specimen TCGA-O2-A52W-01A from TCGA case TCGA-O2-A52W, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 63.4 years (23,156 days).
Specimen TCGA-O2-A52W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.1a1cb9e3-7dee-4291-9450-1b52fa33c1ad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-O2-A52W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d02c9d0d-9b18-4eef-9fae-0860aada17f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 2: 24,272; copy number 3: 13,590; copy number 4: 15,289; copy number 5: 785; copy number 6: 747; copy number 7: 3,159; copy number 8: 1,467; copy number 9: 271; copy number 11: 198; copy number 14: 1; copy number 19: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-O2-A52W-01A-11D-A26L-01): tumor purity 0.36, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:31,165,618–31,381,490, 3 genes: AL354854.1, SLC25A6P2, LINC01243.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,666 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:49,563,388–52,961,452, 28 genes, copy number 5: AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3.
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 7–8 (broad region; genes not listed).
- chr5:58,198–14,992,961, 271 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:75,810,825–116,508,541, 687 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:34,174,886–145,066,685, 1,733 genes, copy number 7–19 (broad region; genes not listed).
- chr10:44,712–38,783,108, 675 genes, copy number 6 (broad region; genes not listed).
- chr12:66,767–27,161,393, 697 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr12:28,133,249–34,249,958, 128 genes, copy number 8 (broad region; genes not listed).
- chr14:78,170,373–79,868,291, 1 gene, copy number 5 (within-gene range 4–5): NRXN3.
- chr14:78,695,321–87,872,291, 74 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:62,187,540–62,357,746, 3 genes, copy number 5: RNU6-21P, AC009161.2, AC009161.1.
- chr19:30,665,274–37,403,846, 261 genes, copy number 6–7 (broad region; genes not listed).
- chr22:37,952,607–38,041,915, 1 gene, copy number 8 (within-gene range 2–8): POLR2F.
- chr22:37,988,794–47,631,569, 305 genes, copy number 8–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
